Gene-level copy-number profile of tumor specimen TCGA-KL-8323-01A from TCGA case TCGA-KL-8323, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.1 years (20,849 days).
Specimen TCGA-KL-8323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.5849a782-86d6-4eca-98e6-c29c312be2e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KL-8323-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6bbb1c6a-8660-43e2-a61a-3748f080f621

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 21,154; copy number 2: 35,430; copy number 3: 3,229.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KL-8323-01A-21D-2308-01): tumor purity 0.92, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:36,639,545–36,687,337, 6 genes: RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 21,154. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
